CPTAC case C3N-05101 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/525aa05b-d7e1-4147-974a-a30b7cafb0cb

Demographics
Sex at birth: female; Race: white; Year of birth: 1943; Vital status: Dead; Days to death: 581 days (1.6 years); Year of death: 2021; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of scalp and neck; Age at diagnosis: 76.9 years (28,084 days); Year of diagnosis: 2020; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T4b; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIID; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 581 days (1.6 years); Days to last follow up: 448 days (1.2 years); Tumor focality: Unifocal; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 3.8 cm; Lymph node involvement: Positive; Lymph nodes positive: 16; Lymph nodes tested: 29; Lymphatic invasion present: Yes; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Targeted Molecular Therapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 448 days (1.2 years); Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 455 days (1.2 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-05101-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 1 day; Initial weight: 92 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-05101-22: Section location: Head & neck; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-05101-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 1 day; Initial weight: 75 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-05101-24: Section location: Head & neck; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-05101-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 1 day; Initial weight: 258 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-05101-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
